Surgical pathology report (de-identified scan), TCGA case TCGA-P8-A5KC, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University of Pittsburgh, specimen TCGA-P8-A5KC-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

ADRENAL GLAND, LEFT, MASS, ADRENALECTOMY (168 GRAMS)-
PHEOCHROMOCYTOMA, 7 CM, 139 GRAMS.

GROSS DESCRIPTION:

The specimen is received fresh labeled with the patient's name, [REDACTED], and "left adrenal mass." The specimen (168 g, 9.5 x 8.6 x 4.5 cm) consists of a left adrenal gland and attached yellow, lobulated adipose tissue. Upon sectioning of the adrenal gland, an encapsulated, rubbery, homogenously red-brown mass with focal fibrosis (139 g, 7 x 5.5 x 4.3 cm) is seen arising from the medulla. The uninvolved adrenal gland appears mildly compressed (5 x 3.5 x 0.5 cm at its widest dimension) with a normal appearing golden-yellow cortex (0.1 cm), inner band of red zona reticularis (<0.1 cm), and innermost core of gray medulla (0.1 cm). Digital images are taken. Tissue from the tumor and uninvolved adrenal gland is procured for clinical tissue banking.

Ink code: Black - mass

Cassette Code:

- 1A - tumor in relation to uninvolved adrenal
- 1B to 1C - areas of mass with focal fibrosis
- 1D - tumor in relation to uninvolved adrenal
- 1E - tumor in relation to capsule

ICD-O-3

Pheochromocytoma NOS

8700/3

Site: Adrenal Gland, medulla

C74.1

GW 3/28/12

Source: NCI Genomic Data Commons file 5898bc85-a32f-4850-b85f-7a8f7702bf31 (TCGA-P8-A5KC.A53180DC-CCD5-4457-87DC-23D92E051751.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).